Somatic mutation profile of tumor specimen TCGA-DU-6405-01A (aliquot TCGA-DU-6405-01A-11D-1705-08) from TCGA case TCGA-DU-6405, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 51.2 years (18,686 days).
Specimen TCGA-DU-6405-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d322aed-047a-4098-b3df-59668df301ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-6405-10A (Blood Derived Normal), aliquot TCGA-DU-6405-10A-01D-1705-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88578dc4-2eef-41a4-91a7-d569d144394c

The open-access MAF lists 54 somatic variants for this specimen: 44 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 34, Silent 10, Nonsense Mutation 4, Frame Shift Del 3, Frame Shift Ins 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 24/87 reads (28%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.797); catalogued as rs587777790, CM130265, COSV55877290; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC013477.1 | c.2614G>A p.A872T | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); catalogued as rs558905999, COSV53654513, COSV53655900; called by muse, mutect2, varscan2
- ADAMTS16 | c.2126G>A p.R709H | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs371654781; called by muse, mutect2, varscan2
- ADGRF1 | c.55G>A p.G19S | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0.019); catalogued as rs766216134, COSV64800785, COSV64801326; called by muse, mutect2, varscan2
- ALPG | c.963C>A p.N321K | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54968499; called by muse, mutect2
- CREBBP | c.5048G>C p.R1683P | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52129686, COSV99268787; called by muse, mutect2, varscan2
- DYNC2H1 | c.334G>A p.V112I | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.031); catalogued as rs756807806, COSV62092111; called by muse, mutect2, varscan2
- FBXO46 | c.574C>T p.R192* | Nonsense Mutation (SNP) | VAF 8/17 reads (47%) | catalogued as rs1192702179, COSV58348114, COSV58349998; called by muse, mutect2, varscan2
- GIGYF2 | c.1837C>T p.Q613* | Nonsense Mutation (SNP) | VAF 18/75 reads (24%) | catalogued as COSV65253953; called by muse, mutect2, varscan2
- GRXCR2 | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV65061592; called by muse, mutect2, varscan2
- GUCY2F | c.141G>T p.Q47H | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0.232); catalogued as COSV54309405; called by muse, mutect2, varscan2
- HBE1 | c.59A>G p.N20S | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.213); catalogued as COSV53081519; called by muse, mutect2, varscan2
- HCN1 | c.1679G>A p.R560H | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV57540284; called by muse, mutect2, varscan2
- HEG1 | c.3982G>T p.D1328Y | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60766126; called by muse, mutect2, varscan2
- HSPD1 | c.1257_1260del p.D419Efs*35 | Frame Shift Del (DEL) | VAF 55/133 reads (41%) | catalogued as rs1215135032; called by mutect2, pindel, varscan2
- ITGA4 | c.2707A>G p.N903D | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.122); catalogued as COSV67899278; called by muse, mutect2, varscan2
- MAGEA6 | c.884G>A p.G295E | Missense Mutation (SNP) | VAF 78/186 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.094); catalogued as rs782059031, COSV61449569; called by muse, mutect2, varscan2
- MYOM3 | c.3988G>A p.E1330K | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as rs777037452, COSV58402003; called by muse, mutect2, varscan2
- OLFML2B | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 73/181 reads (40%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs202036346, COSV54198544; called by muse, mutect2, varscan2
- OPN5 | c.181C>T p.R61* | Nonsense Mutation (SNP) | VAF 42/75 reads (56%) | catalogued as rs767235828, COSV55245590; called by muse, mutect2, varscan2
- PDZD3 | c.1511G>A p.R504Q (on ENST00000531114; = p.R424Q on NM_024791.4) | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.071); catalogued as rs763963387, COSV59541976; called by muse, mutect2, varscan2
- PLP1 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 152/362 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV58278693; called by muse, mutect2, varscan2
- PLPPR1 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.073); catalogued as rs1225180391, COSV66458312; called by muse, mutect2, varscan2
- PSMC4 | c.557C>T p.T186M | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs763454110, COSV50098901; called by muse, mutect2, varscan2
- RASA3 | c.1306C>T p.R436C | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs144637782; called by muse, mutect2, varscan2
- RIMS2 | c.1532C>T p.S511L (on ENST00000666250 / NM_001348490.2; = p.S319L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51650842; called by muse, mutect2, varscan2
- RNF150 | c.559A>G p.I187V | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV60800631; called by muse, mutect2, varscan2
- SI | c.3056G>A p.R1019H | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as rs562524905, COSV52299539, COSV52303895; called by muse, mutect2, varscan2
- SLC17A9 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs781674933, COSV64848542; called by muse, mutect2
- SLC35D3 | c.805G>T p.V269L | Missense Mutation (SNP) | VAF 17/20 reads (85%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as COSV59378467; called by muse, mutect2, varscan2
- SLC46A2 | c.1215A>C p.G405= | Splice Region (SNP) | VAF 21/61 reads (34%) | catalogued as COSV65290577; called by muse, mutect2, varscan2
- SP7 | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as rs753586570, COSV58192180; called by muse, mutect2, varscan2
- SYT16 | c.1301G>A p.R434H | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70860295; called by muse, mutect2, varscan2
- TRIML1 | c.1402G>A p.V468I | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs765434450, COSV60195900; called by muse, mutect2, varscan2
- TYK2 | c.2683C>T p.R895C | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1568328042, COSV53385806, COSV53390127; called by muse, mutect2, varscan2
- TYRP1 | c.1294A>G p.I432V | Missense Mutation (SNP) | VAF 16/17 reads (94%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV66358597; called by muse, mutect2, varscan2
- WDR6 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.901); catalogued as rs766148217, COSV58247820; called by muse, mutect2, varscan2
- ZNF484 | c.652A>G p.T218A | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV60259865; called by muse, mutect2, varscan2
- ZNF624 | c.748G>T p.E250* | Nonsense Mutation (SNP) | VAF 71/150 reads (47%) | catalogued as COSV60941712; called by muse, mutect2, varscan2
- OR5D14 | c.430dup p.A144Gfs*31 | Frame Shift Ins (INS) | VAF 41/101 reads (41%) | called by mutect2, pindel, varscan2
- OTUD3 | c.267dup p.R90Tfs*22 | Frame Shift Ins (INS) | VAF 71/142 reads (50%) | called by mutect2, pindel, varscan2
- PHTF2 | c.1687_1688del p.L563Cfs*16 (on ENST00000248550 / NM_001366089.1; = p.L525Cfs*16 on NM_020432.5 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 40/202 reads (20%) | called by pindel, varscan2
- SCML2 | c.2005_2006del p.K669Efs*2 | Frame Shift Del (DEL) | VAF 68/193 reads (35%) | called by mutect2, pindel, varscan2
- TPTE | c.1107T>A p.F369L (on ENST00000618007 / NM_199261.4; = p.F351L on NM_199259.4) | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, varscan2
- AHNAK2 | c.819G>A p.P273= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as rs1049940812, COSV60932948; called by muse, mutect2, varscan2
- ASB1 | c.477C>A p.I159= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV52828514; called by muse, mutect2, varscan2
- ATXN2 | c.3198T>C p.Y1066= (on ENST00000550104; = p.Y906= on NM_002973.4) | Silent (SNP) | VAF 36/94 reads (38%) | catalogued as rs779874085, COSV66486303; called by muse, mutect2, varscan2
- CDH6 | c.2106G>T p.R702= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV54079500; called by muse, mutect2, varscan2
- FGD5 | c.1758G>A p.S586= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as rs201965283, COSV53252325; called by muse, mutect2, varscan2
- HSPB3 | c.228C>T p.D76= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as rs761293721, COSV57356774, COSV57357254; called by muse, mutect2, varscan2
- KLK6 | c.381G>A p.L127= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV59566869; called by muse, mutect2, varscan2
- P2RY2 | c.201G>A p.A67= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as rs543772574, COSV60778030; called by muse, mutect2, varscan2
- SLC35D3 | c.804G>T p.T268= | Silent (SNP) | VAF 17/20 reads (85%) | catalogued as rs772852547, COSV59378461; called by muse, mutect2, varscan2
- SPPL2C | c.72C>T p.Y24= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as rs754119987, COSV61293907; called by muse, mutect2, varscan2
